Somatic mutation profile of tumor specimen TCGA-C5-A1MJ-01A (aliquot TCGA-C5-A1MJ-01A-11D-A14W-08) from TCGA case TCGA-C5-A1MJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 61.1 years (22,308 days).
Specimen TCGA-C5-A1MJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b50548-b942-4f2f-8d98-5d51a5feb7ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MJ-10A (Blood Derived Normal), aliquot TCGA-C5-A1MJ-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19800455-c0b7-490a-9c5b-4e8bc0fa3a1e

The open-access MAF lists 107 somatic variants for this specimen: 77 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 28, Nonsense Mutation 5, RNA 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 122/315 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV59391853; called by muse, mutect2, varscan2
- A4GNT | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV52630024; called by muse, mutect2, varscan2
- ALG13 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs138712375, COSV99321376; ClinVar: benign / uncertain significance; called by muse, mutect2
- ALKBH5 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs1163702519, COSV67686951; called by muse, mutect2, varscan2
- APOB | c.8738T>G p.L2913R | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.235); catalogued as COSV51950167; called by muse, mutect2, varscan2
- ARHGAP31 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs762629877, COSV51791283; called by muse, mutect2, varscan2
- ASPM | c.8572C>T p.Q2858* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV54137574; called by muse, mutect2, varscan2
- BAHCC1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs374297742; called by muse, mutect2, varscan2
- BRD1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164193595, COSV53456242; called by muse, mutect2, varscan2
- C11orf65 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.075); catalogued as COSV67598494; called by muse, mutect2, varscan2
- C1S | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782226018, COSV61072234; called by muse, mutect2, varscan2
- CACNG7 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs745326651, COSV55817082; called by muse, mutect2, varscan2
- CDK13 | c.3485C>T p.S1162F | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV51699685, COSV51705914; called by muse, mutect2, varscan2
- CES5A | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.838); catalogued as rs745736374, COSV51870124; called by muse, mutect2, varscan2
- CIC | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV50656350, COSV50661745; called by muse, mutect2, varscan2
- CIP2A | c.2144G>T p.R715M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV55421048; called by muse, mutect2, varscan2
- CP | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as COSV52833418; called by muse, mutect2, varscan2
- CX3CL1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV50056812; called by muse, mutect2, varscan2
- DSE | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.025); catalogued as rs867216581, COSV100528535, COSV59067054; called by muse, mutect2, varscan2
- DSG4 | c.2140A>T p.I714F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV57396957; called by muse, mutect2, varscan2
- DYM | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53991682; called by muse, mutect2, varscan2
- E2F3 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60899600; called by mutect2, varscan2
- E2F8 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51465934; called by muse, mutect2, varscan2
- ELOA | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV69311257; called by muse, mutect2, varscan2
- ERBB3 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV57262052; called by muse, mutect2, varscan2
- FERD3L | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762358; called by muse, mutect2, varscan2
- GABRG1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950123, COSV54960963; called by muse, mutect2, varscan2
- GABRG1 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954480, COSV54960971, COSV99777223; called by muse, mutect2, varscan2
- GPR143 | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV101102125; called by muse, mutect2
- KLHDC3 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55065576; called by muse, mutect2, varscan2
- KNDC1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149750022; called by muse, varscan2
- KNTC1 | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV61083581; called by muse, mutect2, varscan2
- LRBA | c.5336C>T p.S1779L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs755264075, COSV100840715; called by muse, mutect2, varscan2
- MAGEB10 | c.875T>G p.L292W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as COSV63312559; called by muse, mutect2
- MAGEB6B | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs771424539; called by muse, mutect2, varscan2
- MDK | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs533427797, COSV58994408; called by muse, mutect2, varscan2
- MYH9 | c.4960C>A p.L1654M | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as COSV53392419; called by muse, mutect2, varscan2
- NCAN | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs370283222; called by muse, mutect2, varscan2
- NEXMIF | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752979291, COSV50130753; called by muse, mutect2
- NTNG2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62368614; called by muse, mutect2, varscan2
- OTOR | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV55722922; called by muse, mutect2
- PCDHA11 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.223); catalogued as rs782072957, COSV56498697; called by muse, mutect2, varscan2
- PCDHGB4 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.437); catalogued as COSV54019833; called by muse, mutect2, varscan2
- PDE11A | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as COSV53706742; called by muse, mutect2, varscan2
- PIWIL4 | c.1566-2A>G p.X522_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54412069; called by muse, mutect2, varscan2
- PKD1L1 | c.5088G>T p.K1696N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.113); catalogued as COSV56964576, COSV56976513; called by muse, mutect2, varscan2
- PLEC | c.9037G>A p.E3013K (on ENST00000322810 / NM_201380.4; = p.E2903K on NM_000445.5) | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782517831, COSV100508929; ClinVar: uncertain significance; called by muse, mutect2
- PLXNA3 | c.3184G>A p.G1062S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV63755499; called by muse, mutect2, varscan2
- QRICH2 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53157365; called by muse, mutect2, varscan2
- RGS2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as COSV52459725; called by muse, mutect2, varscan2
- RIMS1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53480428; called by muse, mutect2, varscan2
- RUFY1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100106157, COSV60163409; called by muse, mutect2, varscan2
- SCN11A | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374311646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC13A1 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV52016238; called by muse, mutect2, varscan2
- SLC18A2 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs934009129, COSV53693290; called by muse, mutect2, varscan2
- SLC1A2 | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53525505; called by muse, mutect2, varscan2
- SLC8A1 | c.2803G>A p.G935S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100243812, COSV60471731; called by muse, mutect2
- SNX29 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV60059469; called by muse, mutect2
- SPATA16 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV63531995, COSV63532782; called by muse, mutect2, varscan2
- STAG3 | c.2530C>A p.H844N | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV57934303; called by muse, mutect2, varscan2
- TNS2 | c.2674C>T p.R892W (on ENST00000314250 / NM_170754.4; = p.R902W on NM_015319.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs771164737, COSV56855791; called by muse, mutect2, varscan2
- TRIM9 | c.1956C>A p.D652E | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53624117; called by muse, mutect2
- TRPC4AP | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV52684097; called by muse, mutect2, varscan2
- TRPM3 | c.2548G>A p.E850K (on ENST00000357533 / NM_001366142.2; = p.E693K on NM_020952.6) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV62593566; called by muse, mutect2, varscan2
- TTC21B | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV54634572; called by muse, mutect2, varscan2
- TTN | c.39292G>C p.D13098H (on ENST00000591111; = p.D5674H on NM_003319.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | PolyPhen possibly damaging (0.8); catalogued as COSV60012297, COSV60304009; called by muse, mutect2
- UHRF1BP1 | c.4282C>T p.L1428F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV51959836; called by muse, mutect2, varscan2
- ULK2 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 73/179 reads (41%) | catalogued as COSV64445472; called by muse, mutect2, varscan2
- UPF2 | c.2941G>C p.E981Q | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.729); catalogued as COSV62663415; called by muse, mutect2, varscan2
- USP11 | c.2590G>A p.E864K (on ENST00000218348; = p.E821K on NM_001371072.1) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.075); catalogued as COSV54475774, COSV99510855; called by muse, mutect2, varscan2
- ZC3H12A | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV66104516; called by muse, mutect2, varscan2
- ZFP36 | c.122C>T p.S41L (on ENST00000594442; = p.S35L on NM_003407.5) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs954583210, COSV50531123; called by muse, mutect2, varscan2
- ZNF454 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60766602, COSV60770189; called by muse, mutect2, varscan2
- ETV4 | c.88_94del p.E30* | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- KIF5B | c.2483del p.Q828Rfs*47 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- SRRM2 | c.3274dup p.T1092Nfs*4 | Frame Shift Ins (INS) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- ACTA1 | c.69C>T p.F23= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1339913000, COSV64202957; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD34A | c.1107G>A p.L369= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV60161926; called by muse, mutect2, varscan2
- DOCK1 | c.555C>T p.F185= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as rs554024311, COSV54757391; called by muse, mutect2, varscan2
- EHMT2 | c.417A>G p.K139= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100976928; called by muse, mutect2
- FOXJ3 | c.939G>A p.L313= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs766796237, COSV100691321; called by muse, mutect2
- GALNT5 | c.2808A>G p.K936= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV52040791; called by muse, mutect2, varscan2
- HERC2 | c.483G>A p.E161= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV55347000; called by muse, mutect2, varscan2
- KCNS3 | c.1155C>T p.L385= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs1185849583, COSV58408726; called by muse, mutect2, varscan2
- KCTD16 | c.684C>G p.L228= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV101568665; called by muse, mutect2
- KDM4D | c.672A>G p.E224= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV58636264; called by muse, mutect2, varscan2
- KMT2C | c.12867G>A p.V4289= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100064099; called by muse, mutect2, varscan2
- LAMB1 | c.3771T>C p.I1257= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV55969640; called by muse, mutect2, varscan2
- LPIN2 | c.1110G>A p.A370= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1349998517, COSV55243679; called by muse, mutect2, varscan2
- MAST4 | c.1125C>G p.V375= (on ENST00000403625 / NM_001164664.2; = p.V186= on NM_015183.3) | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV55138565, COSV55139886; called by muse, mutect2, varscan2
- MCAM | c.393C>T p.R131= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs767744036, COSV50679955; called by muse, mutect2, varscan2
- MOV10L1 | c.3486G>A p.L1162= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV53178264; called by muse, mutect2, varscan2
- OR1M1 | c.486G>A p.L162= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs770870710, COSV70037489; called by muse, mutect2, varscan2
- PCDHB3 | c.1563C>T p.Y521= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs782347010, COSV50607432, COSV50625007; called by muse, mutect2, varscan2
- PLEC | c.11220G>A p.Q3740= (on ENST00000322810 / NM_201380.4; = p.Q3630= on NM_000445.5) | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV59689543; called by muse, mutect2, varscan2
- PPP2CB | c.228G>A p.P76= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs1378471067, COSV55329411; called by muse, mutect2, varscan2
- RPS26 | c.156C>T p.D52= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100008789; called by muse, mutect2
- SMAD1 | c.183G>A p.P61= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs773218247, COSV57473172; called by muse, mutect2, varscan2
- TPX2 | c.1284C>T p.T428= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs778161513, COSV55922466; called by muse, mutect2, varscan2
- TUBGCP2 | c.2454C>T p.F818= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs370230871, COSV53308457; called by muse, mutect2
- UBAC1 | c.153C>T p.S51= | Silent (SNP) | VAF 151/349 reads (43%) | catalogued as COSV65614648; called by muse, mutect2, varscan2
- WNK2 | c.6300C>T p.L2100= (on ENST00000297954 / NM_001282394.1; = p.L2063= on NM_006648.3) | Silent (SNP) | VAF 46/200 reads (23%) | catalogued as COSV99940513; called by muse, mutect2, varscan2
- ZNF546 | c.234C>T p.D78= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs760436332, COSV61258452; called by muse, mutect2, varscan2
- ZNF606 | c.732T>C p.A244= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs1467231486, COSV62048943; called by muse, mutect2, varscan2
- MIR1205 | n.15G>C | RNA (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- NBPF25P | n.1958G>A | RNA (SNP) | VAF 8/122 reads (7%) | called by muse, varscan2
